Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3H3, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3H3-01A (Primary Tumor).

Pathology port

Pathology,
Fax:

DOB:
Physician:

Sex: F

Accession:

Collected:

Received:

Case type: Surgical Case

1CD-0-3

Carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C93.9 lw 11/30/11

DIAGNOSIS

(A) PRESTRAP MUSCLE TISSUE, EXCISION:

Fibroconnective tissue and skeletal muscle, no tumor present.

(B) RIGHT PARATHYROID, BIOPSY:

Hypercellular parathyroid tissue, 0.004 grams.

(C) THYROID, TOTAL THYROIDECTOMY:

POORLY-DIFFERENTIATED THYROID CARCINOMA WITH PAPILLARY COMPONENT.

Location: Isthmus

Multi-focal: No

Size = 2.7 cm

Extrathyroidal extension: Absent

Lymphovascular invasion: Absent

Resection Margins: Negative

Background Thyroid: Extensive chronic lymphocytic thyroiditis consistent with Hashimoto's thyroiditis

Parathyroid tissue in superior right and left lobes

Lymph nodes:

METASTATIC PAPILLARY THYROID CARCINOMA IN ONE LYMPH NODE (1/1)

Location: Central, neck

Extracapsular extension: Absent

(D) PARATHYROID, RIGHT SUPERIOR, BIOPSY:

Lymphoid tissue, no tumor present.

No parathyroid tissue present.

(E) PARATHYROID, LEFT SUPERIOR, BIOPSY:

Lymphoid tissue, no tumor present.

No parathyroid tissue present.

(F) BILATERAL PARATRACHEAL AND MEDIASTINAL LYMPH NODES, DISSECTION:

METASTATIC PAPILLARY THYROID CARCINOMA IN FIVE OF EIGHTEEN LYMPH NODES (5/18).

Fragments of thyroid tissue with lymphocytic thyroiditis.

GROSS DESCRIPTION

(A) PRESTRAP MUSCLE TISSUE – One strip of fibroadipose tissue, 7.0 x 1.0 x 0.5 cm. The specimen is serially sectioned. The cut surface reveals unremarkable fibroadipose tissue. Representative section submitted in A1 and A2.

(B) RULE OUT PARATHYROID – Received is a pink tissue measuring 0.2 x 0.2 x 0.1 cm and weighing 0.004 grams. Touch preparation is obtained and the specimen is entirely submitted in B for frozen section.

*FS/DX: CONSISTENT WITH HYPERCELLULAR PARATHYROID.

Source: NCI Genomic Data Commons file 2935d42b-ba34-4f71-bd99-b82e326c2aba (TCGA-EL-A3H3.397F6046-731D-4689-A52E-8C6C415D4132.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).